Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A70J, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A70J-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology

Final Results

Surgical Pathology

Final

CASE NUMBER:

DIAGNOSIS:

1. Adrenal gland, right, adrenalectomy: Consistent with pheochromocytoma (3.4 cm in greatest dimension). See Note.
2. Skin, right lower back lesion, biopsy: Neurofibroma.

NOTE: The tumor is composed of nests of neuroendocrine cells, partially separated by a delicate collagenous stroma and sustentacular cells. Immunostaining for chromogranin and synaptophysin are strong and diffuse. S100 highlights sustentacular cells. Inhibin is negative.

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the Laboratory of Pathology; they have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Allocate Order to Protocol: Brief
Clinical History: Patient
with right adrenal lesion ? Pheochromocytoma Specimen Taken For
Protocol: 01 - Yes

PROCEDURE: Pre-Operative Diagnosis: Right adrenal mass Post-Operative
Diagnosis:
As above Operative Findings: Enlarged inferior pole of right adrenal
gland

SPECIMENS SUBMITTED: 1. ADRENAL GLAND, RIGHT; Paraganglioma
2. BACK LESION, Right lower

GROSS DESCRIPTION:

1. Received fresh in a container labeled with patient's name, medical record number, and labeled "right adrenal gland/paraganglioma path/research" is a right adrenalectomy specimen focally covered by adipose tissue overall measuring 8.7 x 4.2 x 2.8 cm and weighing 35.3 grams. The external surface is inked black. There is a palpable pink ovoid nodule at one end measuring 3.4 x 2.6 x 2.6 cm. One cut is made revealing a soft maroon-pink variegated hemorrhage cut surface in the nodule.

[page 2 of 2]
Gross photographs are taken. Approximately 50% of tissue from the center of the nodule is procured for The procurement was performed by hour. The specimen is received in Pathology and matches the above description. A representative section of the nodule in the area where procurement took place is taken and placed into a white cassette labeled . A representative section from the other mirror image side where procurement took place is taken and placed into a white cassette labeled . Upon sectioning, the nodule measures 3.5 x 2.5 x 2.5 cm. Sectioning through the remainder of the specimen reveals no other obvious nodules. The remainder of the adrenal gland has a normal golden yellow cortex with an inner central pearly gray medulla and is surrounded by adipose tissue measuring up to 1.2 cm in greatest dimension. The remainder of the serially sectioned specimens are entirely submitted in white cassettes labeled with cassettes and being in closest proximity to the region of the nodule which was procured from.

2. Received in a specimen container in formalin labeled with the patient's name, medical record number, and "right lower back lesion" is a circular soft tissue fragment that appears to contain skin and dermis. The section of skin measures 1.2 cm in diameter x 0.7 cm in depth. It is trisected and entirely submitted in a white cassette labeled

Gross description dictated by

No consultants

Accessioned:

Final Report Signed Out:

<Resident Signature>

<Sign Out Dr. Signature>

Date Report Signed:

Source: NCI Genomic Data Commons file 0e316b48-5f38-49af-ac4f-40579a8b1163 (TCGA-QR-A70J.0B0154CD-26BF-413D-93E1-6693C9E86AA2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).